Somatic mutation profile of tumor specimen TCGA-F2-A44G-01A (aliquot TCGA-F2-A44G-01A-11D-A26I-08) from TCGA case TCGA-F2-A44G, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 79.8 years (29,150 days).
Specimen TCGA-F2-A44G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9f934fa-3093-446b-8108-ee6c7a6d00a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F2-A44G-10A (Blood Derived Normal), aliquot TCGA-F2-A44G-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67d8f2a1-d504-4260-bfed-d9efcea49201

The open-access MAF lists 48 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Nonsense Mutation 6, 5'UTR 1, Splice Region 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 17/127 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- METTL14 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 86/735 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- APOBEC3B | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as rs751320407, COSV100213808; called by muse, mutect2, varscan2
- AQR | c.3193G>T p.A1065S | Missense Mutation (SNP) | VAF 53/462 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99334260; called by muse, mutect2, varscan2
- ATP6V0A4 | c.351G>C p.L117F | Missense Mutation (SNP) | VAF 96/636 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59477480; called by muse, mutect2, varscan2
- BPIFB2 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 165/1134 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50066187; called by muse, mutect2, varscan2
- CCNF | c.1003G>T p.V335L | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV53540472, COSV99563840; called by muse, mutect2, varscan2
- CDK20 | c.787G>T p.D263Y (on ENST00000325303 / NM_001039803.3; = p.D242Y on NM_012119.4) | Missense Mutation (SNP) | VAF 145/1026 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV100308140; called by muse, mutect2, varscan2
- CPXM2 | c.2257C>T p.R753* | Nonsense Mutation (SNP) | VAF 78/580 reads (13%) | catalogued as rs755249876, COSV53857499; called by muse, mutect2, varscan2
- CSMD2 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 148/958 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs756045595, COSV99592111; called by muse, mutect2, varscan2
- CSTF2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 98/856 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1457383580, COSV63376195; called by muse, mutect2, varscan2
- CYP27A1 | c.1114G>C p.G372R | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as COSV99298578, COSV99298786; called by muse, mutect2, varscan2
- DDX60L | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776813390, COSV99487479, COSV99487904; called by muse, mutect2, varscan2
- DLGAP2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs774180756, COSV70097614; called by muse, mutect2, varscan2
- DNAH9 | c.12310G>A p.D4104N | Missense Mutation (SNP) | VAF 55/370 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99306683; called by muse, mutect2, varscan2
- DPYD | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs267598789, COSV64596718; called by muse, mutect2, varscan2
- EEF2 | c.1371C>A p.Y457* | Nonsense Mutation (SNP) | VAF 25/219 reads (11%) | catalogued as COSV100500835, COSV100500896, COSV58580632; called by muse, mutect2, varscan2
- GPR26 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.131); catalogued as COSV52932406; called by muse, mutect2, varscan2
- HELQ | c.2852G>A p.W951* | Nonsense Mutation (SNP) | VAF 39/267 reads (15%) | catalogued as COSV99787879; called by muse, mutect2, varscan2
- HEXB | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs750001501, COSV99784335; called by muse, mutect2, varscan2
- KRT76 | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 36/272 reads (13%) | catalogued as COSV100196336; called by muse, mutect2, varscan2
- MALL | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757582506, COSV55600831; called by muse, mutect2
- METTL14 | c.67-2A>G p.X23_splice | Splice Site (SNP) | VAF 49/273 reads (18%) | catalogued as rs1480089342, COSV101183409; called by muse, mutect2, varscan2
- MMP3 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 56/565 reads (10%) | catalogued as COSV100242892; called by muse, mutect2, varscan2
- PCDHB11 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 172/1176 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV61309917; called by muse, mutect2, varscan2
- RTN3 | c.2869T>A p.S957T (on ENST00000377819 / NM_001265589.2; = p.S161T on NM_006054.4) | Missense Mutation (SNP) | VAF 132/970 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100380243; called by muse, mutect2, varscan2
- SETDB1 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 77/588 reads (13%) | catalogued as COSV99645188; called by muse, mutect2, varscan2
- TEX13A | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as COSV100781575; called by muse, mutect2, varscan2
- TRPC7 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as rs762550006, COSV61456185, COSV61459623; called by muse, mutect2, varscan2
- VCAN | c.3983A>G p.E1328G | Missense Mutation (SNP) | VAF 68/480 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99426412; called by muse, mutect2, varscan2
- ZFPM2 | c.3067G>A p.G1023R | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV101023301; called by muse, mutect2
- ZFYVE26 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.761); catalogued as rs778438729, COSV61333493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF667 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 63/583 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99410678; called by muse, mutect2, varscan2
- ZNF835 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 78/527 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1412785695, COSV73379766; called by muse, mutect2, varscan2
- MED14 | c.2648del p.N883Tfs*11 | Frame Shift Del (DEL) | VAF 51/466 reads (11%) | called by mutect2, pindel, varscan2
- MRC1 | c.1547A>G p.Y516C | Missense Mutation (SNP) | VAF 107/680 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASGEF1B | c.-5_-2del | Splice Region (DEL) | VAF 27/278 reads (10%) | called by mutect2, pindel
- ANKH | c.477C>T p.F159= | Silent (SNP) | VAF 56/332 reads (17%) | catalogued as rs866554190, COSV52477289; called by muse, varscan2
- ATG9B | c.978G>A p.S326= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV99871872; called by muse, mutect2, varscan2
- DHDH | c.873C>T p.H291= | Silent (SNP) | VAF 75/546 reads (14%) | catalogued as rs377571592; called by muse, mutect2, varscan2
- GRIN2A | c.1338C>A p.T446= | Silent (SNP) | VAF 62/469 reads (13%) | catalogued as COSV100410367; called by muse, mutect2, varscan2
- JAK3 | c.2535C>T p.G845= | Silent (SNP) | VAF 93/685 reads (14%) | catalogued as rs200746503, COSV71687359; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMX1A | c.795G>A p.Q265= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as COSV99672684; called by muse, mutect2, varscan2
- MYH2 | c.3384C>T p.I1128= | Silent (SNP) | VAF 67/441 reads (15%) | catalogued as rs139130605; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MYLK | c.3489G>A p.E1163= | Silent (SNP) | VAF 15/364 reads (4%) | catalogued as COSV100659286; called by muse, mutect2
- OR51B5 | c.234G>A p.T78= | Silent (SNP) | VAF 47/337 reads (14%) | catalogued as rs369884002; called by muse, mutect2, varscan2
- MLLT6 | c.819+250A>G | Intron (SNP) | VAF 69/400 reads (17%) | called by muse, mutect2, varscan2
- RPL14 | c.-1C>G | 5'UTR (SNP) | VAF 12/117 reads (10%) | catalogued as rs200788022, COSV100166249; called by muse, mutect2
